Somatic mutation profile of tumor specimen ALCH-ABRX-TTP1-A (aliquot ALCH-ABRX-TTP1-A-1-0-D-A489-36) from ALCHEMIST case ALCH-ABRX, project ALCHEMIST-ALCH (Adjuvant Lung Cancer Enrichment Marker Identification and Sequencing Trial). Sex at birth: female; Primary diagnosis: Adenocarcinoma, NOS; Age at diagnosis: 55.9 years (20,411 days).
Specimen ALCH-ABRX-TTP1-A: Sample type: FFPE Scrolls; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Solid Tissue; Preservation method: FFPE.
Source: NCI Genomic Data Commons open-access Masked Somatic Mutation file (Mutation Annotation Format, MAF) d3d1285c-9c5d-42f2-a2cd-9605a064543a.wxs.aliquot_ensemble_masked.maf.gz, workflow Aliquot Ensemble Somatic Variant Merging and Masking; Data Release 46.0 - August 10, 2026. Variants were called in the tumor against matched normal specimen ALCH-ABRX-NB1-A (Blood Derived Normal), aliquot ALCH-ABRX-NB1-A-1-0-D-A489-36; read counts below are tumor reads.
https://portal.gdc.cancer.gov/files/ce231233-41d8-4c19-87b7-8ff7f8f42ca2

The open-access MAF lists 51 somatic variants for this specimen: 30 protein-altering or splice-affecting, 14 silent, 7 other (UTR, intronic, flanking, RNA and similar).
By variant classification: Missense Mutation 28, Silent 14, Intron 3, In Frame Del 1, Frame Shift Del 1, 5'UTR 1, 5'Flank 1, 3'UTR 1, RNA 1.

Variants (all; order: hotspot or ClinVar-pathogenic variants first, then other protein-altering variants with a dbSNP/COSMIC/ClinVar record ('catalogued as' / 'ClinVar'), then the remaining protein-altering, then silent, then non-coding — alphabetical by gene within each group; each line: gene | DNA and protein change | classification | tumor variant allele fraction (VAF) | annotations). Protein positions are numbered on GDC's canonical Ensembl transcript (GENCODE v36); where an older RefSeq transcript numbers the protein differently, the line names both transcripts and gives that numbering too:
- EGFR | c.2235_2249del p.E746_A750del | In Frame Del (DEL) | VAF 135/563 reads (24%) | hotspot (GDC flag); catalogued as rs121913421, COSV51765119; ClinVar: drug response; called by mutect2, pindel, varscan2
- TP53 | c.796G>C p.G266R | Missense Mutation (SNP) | VAF 64/485 reads (13%) | hotspot (GDC flag); SIFT deleterious (0.03); PolyPhen probably damaging (0.951); catalogued as rs1057519990, COSV52670619, COSV52672762, COSV52751844; ClinVar: pathogenic / uncertain significance / likely pathogenic; called by muse, mutect2, varscan2
- CC2D2A | c.4301T>C p.I1434T | Missense Mutation (SNP) | VAF 11/79 reads (14%) | SIFT deleterious (0); PolyPhen probably damaging (0.977); catalogued as rs776481009; called by muse, mutect2, varscan2
- DES | c.20C>T p.S7F | Missense Mutation (SNP) | VAF 22/104 reads (21%) | SIFT deleterious (0.03); PolyPhen probably damaging (0.979); catalogued as rs903985237, CM1110330; ClinVar: uncertain significance; called by muse, mutect2, varscan2
- ELF3 | c.752G>C p.R251P | Missense Mutation (SNP) | VAF 16/115 reads (14%) | SIFT tolerated (0.36); PolyPhen probably damaging (0.998); catalogued as COSV100668959, COSV62839131, COSV62839867; called by muse, mutect2, varscan2
- GPR119 | c.394G>A p.V132M | Missense Mutation (SNP) | VAF 32/266 reads (12%) | SIFT tolerated (0.07); PolyPhen benign (0.272); catalogued as COSV52275957; called by muse, mutect2, varscan2
- LIMK1 | c.665G>A p.R222Q | Missense Mutation (SNP) | VAF 22/264 reads (8%) | SIFT deleterious (0.03); PolyPhen possibly damaging (0.846); catalogued as rs148676592; called by muse, mutect2
- PCDHB1 | c.1358G>A p.R453Q | Missense Mutation (SNP) | VAF 36/298 reads (12%) | SIFT tolerated (0.11); PolyPhen benign (0); catalogued as rs199588864, COSV60631507; called by muse, mutect2, varscan2
- PTPRD | c.5152del p.Q1718Rfs*22 | Frame Shift Del (DEL) | VAF 29/165 reads (18%) | catalogued as COSV61952776; called by mutect2, pindel, varscan2
- SAMD9 | c.2363G>A p.R788H | Missense Mutation (SNP) | VAF 49/370 reads (13%) | SIFT tolerated (1); PolyPhen benign (0); catalogued as rs780363399, COSV66073530, COSV66076252; called by muse, mutect2, varscan2
- SDK2 | c.2296G>A p.E766K | Missense Mutation (SNP) | VAF 18/268 reads (7%) | SIFT deleterious (0.01); PolyPhen benign (0.15); catalogued as rs893166688; called by muse, mutect2
- SPATA31A1 | c.3679C>T p.R1227C | Missense Mutation (SNP) | VAF 88/745 reads (12%) | SIFT tolerated (0.11); PolyPhen possibly damaging (0.459); catalogued as rs1468217021; called by muse, mutect2, varscan2
- TTF2 | c.1057G>T p.D353Y | Missense Mutation (SNP) | VAF 20/166 reads (12%) | SIFT deleterious (0); PolyPhen possibly damaging (0.848); catalogued as rs146799971, COSV65634265; called by muse, varscan2
- UNC45B | c.782G>A p.R261Q | Missense Mutation (SNP) | VAF 25/155 reads (16%) | SIFT tolerated (0.06); PolyPhen benign (0.104); catalogued as rs1044656347; called by muse, mutect2, varscan2
- ZMAT1 | c.1192G>T p.D398Y | Missense Mutation (SNP) | VAF 21/185 reads (11%) | SIFT deleterious (0); PolyPhen probably damaging (0.997); catalogued as COSV100858887; called by muse, mutect2, varscan2
- ABCC4 | c.1426G>C p.A476P | Missense Mutation (SNP) | VAF 9/123 reads (7%) | SIFT deleterious (0); PolyPhen probably damaging (0.974); called by muse, mutect2
- BCOR | c.553A>T p.S185C | Missense Mutation (SNP) | VAF 52/431 reads (12%) | SIFT deleterious (0); PolyPhen probably damaging (0.997); called by muse, mutect2, varscan2
- EBF4 | c.760G>T p.A254S (on ENST00000609451; = p.A250S on NM_001110514.1) | Missense Mutation (SNP) | VAF 41/157 reads (26%) | SIFT tolerated (0.12); PolyPhen benign (0.048); called by muse, mutect2, varscan2
- GPC3 | c.850G>A p.G284S | Missense Mutation (SNP) | VAF 47/410 reads (11%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.996); called by muse, mutect2, varscan2
- LAMC3 | c.4473G>T p.R1491S | Missense Mutation (SNP) | VAF 77/569 reads (14%) | SIFT tolerated (0.48); PolyPhen benign (0.003); called by muse, mutect2, varscan2
- LPAR6 | c.478C>G p.Q160E | Missense Mutation (SNP) | VAF 18/188 reads (10%) | SIFT tolerated (1); PolyPhen benign (0.01); called by muse, mutect2
- LPAR6 | c.18C>G p.S6R | Missense Mutation (SNP) | VAF 18/132 reads (14%) | SIFT tolerated (0.27); PolyPhen benign (0.039); called by muse, mutect2, varscan2
- MYO18A | c.2752C>T p.L918F | Missense Mutation (SNP) | VAF 34/181 reads (19%) | SIFT deleterious (0.05); PolyPhen probably damaging (0.959); called by muse, mutect2, varscan2
- NEUROD6 | c.607C>T p.P203S | Missense Mutation (SNP) | VAF 22/214 reads (10%) | SIFT tolerated (0.28); PolyPhen probably damaging (0.998); called by muse, mutect2, varscan2
- NNT | c.229G>T p.A77S | Missense Mutation (SNP) | VAF 37/254 reads (15%) | SIFT tolerated (0.55); PolyPhen benign (0.114); called by muse, varscan2
- SLC35E1 | c.134A>G p.N45S | Missense Mutation (SNP) | VAF 31/165 reads (19%) | SIFT tolerated (0.17); PolyPhen benign (0.338); called by muse, mutect2, varscan2
- TAS2R19 | c.347T>A p.L116H | Missense Mutation (SNP) | VAF 23/204 reads (11%) | SIFT tolerated (0.05); PolyPhen benign (0.178); called by muse, mutect2, varscan2
- THRAP3 | c.2162T>G p.I721S | Missense Mutation (SNP) | VAF 8/57 reads (14%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); called by muse, mutect2
- UPF1 | c.583G>A p.G195S | Missense Mutation (SNP) | VAF 21/152 reads (14%) | SIFT deleterious (0); PolyPhen probably damaging (0.997); called by muse, mutect2, varscan2
- VARS1 | c.3760G>A p.D1254N | Missense Mutation (SNP) | VAF 20/224 reads (9%) | SIFT tolerated (0.3); PolyPhen benign (0); called by muse, mutect2
- ABCC3 | c.2376C>T p.H792= | Silent (SNP) | VAF 25/196 reads (13%) | catalogued as rs150740244; called by muse, mutect2, varscan2
- ADCY1 | c.1050C>T p.L350= | Silent (SNP) | VAF 14/295 reads (5%) | catalogued as rs1358513668, COSV52030617; called by muse, mutect2
- AKR1A1 | c.258C>T p.H86= | Silent (SNP) | VAF 8/109 reads (7%) | called by muse, mutect2
- FIGNL1 | c.138A>G p.A46= | Silent (SNP) | VAF 18/192 reads (9%) | called by muse, mutect2
- HECTD4 | c.11235C>T p.P3745= | Silent (SNP) | VAF 17/125 reads (14%) | catalogued as rs778304305; called by muse, mutect2, varscan2
- HIPK3 | c.2943C>G p.S981= | Silent (SNP) | VAF 37/339 reads (11%) | called by muse, mutect2
- KRT26 | c.234C>T p.L78= | Silent (SNP) | VAF 10/196 reads (5%) | called by muse, mutect2
- LPAR6 | c.708C>T p.I236= | Silent (SNP) | VAF 15/168 reads (9%) | called by muse, mutect2
- PAGE4 | c.45T>C p.G15= | Silent (SNP) | VAF 16/261 reads (6%) | called by muse, mutect2
- PCDH10 | c.1593C>T p.F531= | Silent (SNP) | VAF 71/374 reads (19%) | catalogued as COSV52087352, COSV52088569; called by muse, mutect2, varscan2
- POMK | c.948G>A p.Q316= | Silent (SNP) | VAF 17/146 reads (12%) | called by muse, mutect2, varscan2
- POP1 | c.2490G>T p.R830= | Silent (SNP) | VAF 67/273 reads (25%) | called by muse, mutect2, varscan2
- WNT16 | c.465C>T p.N155= (on ENST00000222462 / NM_057168.2; = p.N145= on NM_016087.2) | Silent (SNP) | VAF 102/394 reads (26%) | catalogued as rs934853239; called by muse, mutect2, varscan2
- ZNF469 | c.3588G>A p.E1196= (on ENST00000437464; = p.E1224= on NM_001367624.2) | Silent (SNP) | VAF 46/247 reads (19%) | catalogued as rs757366332; called by muse, mutect2, varscan2
- ADAM20P1 | n.1536G>A | RNA (SNP) | VAF 13/105 reads (12%) | catalogued as rs1228493886; called by muse, mutect2, varscan2
- CYP27B1 | c.589+27G>A | Intron (SNP) | VAF 50/262 reads (19%) | called by muse, mutect2, varscan2
- ODF2 | c.-218C>T | 5'UTR (SNP) | VAF 18/95 reads (19%) | called by muse, mutect2, varscan2
- SDR39U1 | c.206+126_206+130del | Intron (DEL) | VAF 50/254 reads (20%) | called by mutect2, pindel, varscan2
- SHISA6 | c.800-3794C>T | Intron (SNP) | VAF 21/119 reads (18%) | called by muse, mutect2, varscan2
- SLC16A12 | c.*2394T>G | 3'UTR (SNP) | VAF 9/103 reads (9%) | called by muse, mutect2
- TIMM23 | chr10:45972092 A>T | 5'Flank (SNP) | VAF 35/240 reads (15%) | called by muse, mutect2, varscan2
